RC case RC-B6S6 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/69640bf7-9bf3-42ca-92bd-6d6449a30e2a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive.

Diagnoses (1)
1. Angioimmunoblastic T-cell lymphoma: ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of axilla or arm; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,303 days); Year of diagnosis: 2013; Method of diagnosis: Excisional Biopsy; Prior malignancy: no; Synchronous malignancy: No; International Prognostic Index (IPI): Low Risk.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: -14 days; Days to treatment end: 176 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CEOP; Days to treatment start: -14 days; Days to treatment end: 176 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Recorded as not given: Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous.

Follow-up (2 entries)
- Day 50 (end of treatment course 1): Disease response: Tumor Free.
- Follow-up contact recording only the day: day 2,032.

Molecular and laboratory tests
- Lactate Dehydrogenase 713 U/L [Blood test normal range upper: 618].

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6S6-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6S6-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6S6-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
